HCMI case HCM-BROD-0449-C34 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/dd88a8a4-517b-40ad-a4f3-201e20875cfe

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1945; Vital status: Alive.

Diagnoses (1)
1. Carcinoma, NOS: ICD-O-3 morphology code: 8010/3; ICD-10 code: C79.3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: metastasis; Age at diagnosis: 72.3 years (26,423 days); AJCC staging edition: 7th; AJCC clinical stage: Stage IV; AJCC pathologic T: T1b; AJCC pathologic N: N1; AJCC pathologic M: M1b; AJCC pathologic stage: Stage IV; Tumor grade: G3; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: yes; Prior treatment: Yes; Sites of involvement: Brain, NOS.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: -14 days.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Maintenance Therapy; Initial disease status: Progressive Disease; Days to treatment start: 232 days; Days to treatment end: 232 days; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Stereotactic Radiosurgery; Treatment intent type: Neoadjuvant; Days to treatment start: 232 days.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS, for residual disease; neoadjuvant Pharmaceutical Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Brain, NOS; Days to progression: 0 days.
- Days to follow up: 386 days (1.1 years); Progression or recurrence: Yes; Progression or recurrence anatomic site: Brain, NOS; Days to progression: 386 days (1.1 years).
- Days to follow up: 632 days (1.7 years); Disease response: Progressive Disease; Progression or recurrence: Yes.

Molecular and laboratory tests
- CD274 (IHC): Negative.
- EML4–ALK translocation (IHC): Negative; Second exon: 20.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 80 kg; Height: 178 cm; BMI: 25.2.

Exposures
- Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 50; Tobacco smoking quit year: 2015.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Cancer.

Biospecimens (3 samples)
- Sample HCM-BROD-0449-C34-10B: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-BROD-0449-C34-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 2D Modified Conditionally Reprogrammed Cells; Preservation method: Frozen; Passage count: 11.
- Sample HCM-BROD-0449-C34-86M: Sample type: Expanded Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen.
